Somatic mutation profile of tumor specimen TCGA-BJ-A28X-01A (aliquot TCGA-BJ-A28X-01A-11D-A22D-08) from TCGA case TCGA-BJ-A28X, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 32.1 years (11,735 days).
Specimen TCGA-BJ-A28X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de412815-e448-4012-9155-1e441963d011.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A28X-10A (Blood Derived Normal), aliquot TCGA-BJ-A28X-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d03a41ff-b820-45b9-a8d1-bfb335dd56a5

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CEP128 | c.1999G>A p.D667N | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV55392225; called by muse, mutect2, varscan2
- MEFV | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as rs201025181, COSV54828197; called by muse, mutect2, varscan2
- OSBP | c.458A>G p.N153S | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.402); catalogued as COSV55666037; called by muse, mutect2, varscan2
- INF2 | c.1905C>T p.A635= | Silent (SNP) | VAF 13/232 reads (6%) | catalogued as COSV53036924; called by muse, mutect2
